MMRF case MMRF_1650 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7fac98c8-5e59-4b35-8fc0-465621d2f921

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.9 years (30,292 days); ISS stage: III; Days to last known disease status: 997 days (2.7 years); Days to last follow up: 997 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 316 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 316 days; Days to treatment end: 486 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 486 days (1.3 years); Days to treatment end: 659 days (1.8 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 652 days (1.8 years); Days to treatment end: 997 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 666 days (1.8 years); Days to treatment end: 997 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 562 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 5.59 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 268 µmol/L; Blood Urea Nitrogen 26.1 mmol/L; Calcium 2.73 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 12.3 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 92 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 405 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.6 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 7.59 mmol/L.
- Day 180 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 5.49 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 5.55 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 5.5 g/dL; Glucose 5.12 mmol/L.
- Day 257 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 47.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 4.67 g/L; Immunoglobulin M 0 g/L; Hemoglobin 5.33 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 5.06 mmol/L.
- Day 344: M Protein 0.2 g/dL; Immunoglobulin G 7.36 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 19.3 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 6.05 mmol/L.
- Day 458 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 118 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.78 mg/dL; Immunoglobulin G 9.44 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 20 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 561 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 114 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 5.39 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 5.56 mmol/L.
- Day 631 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 256 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 9.24 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 4.77 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 24.6 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 7.48 mmol/L.
- Day 743 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 305 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.91 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 230 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 6.27 mmol/L.
- Day 771 (ECOG 2): Hemoglobin 5.52 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 190 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.79 mmol/L.
- Day 866 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 267 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.78 mg/dL; Hemoglobin 4.96 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 997 (ECOG 2): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 535 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.5 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 23.9 mmol/L; Calcium 2.98 mmol/L; Albumin 49 g/L; Total Protein 8.1 g/dL; Glucose 10.9 mmol/L.

Other clinical attributes
- Day -6: Weight: 63 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1650_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1650_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
- Sample MMRF_1650_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 631 days (1.7 years).
